MMRF case MMRF_1730 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0fb023d4-1952-45f7-a1da-aa38edb9c199

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 50.8 years (18,560 days); ISS stage: I; Days to last known disease status: 1,152 days (3.2 years); Days to last follow up: 1,152 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 33 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 36 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 92 days; Days to treatment end: 92 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 117 days; Days to treatment end: 117 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 118 days; Days to treatment end: 118 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 705 days (1.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 706 days (1.9 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Regimen or line of therapy: Second line of therapy; Days to treatment start: 854 days (2.3 years); Days to treatment end: 854 days (2.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -22 (ECOG 1): M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 101 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.527 mg/dL; Immunoglobulin G 45.7 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 9.7 g/dL; Glucose 4.13 mmol/L.
- Day 92 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.548 mg/dL; Immunoglobulin G 6.8 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.91 g/L; Beta 2 Microglobulin 1.48 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.3 g/dL; Glucose 4.35 mmol/L.
- Day 174 (ECOG 1): Hemoglobin 8.06 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 156 ×10⁹/L.
- Day 235 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.708 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 47 g/L; Total Protein 6.7 g/dL; Glucose 9.63 mmol/L.
- Day 291 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.576 mg/dL; Immunoglobulin G 8.26 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 46 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L.
- Day 599 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.983 mg/dL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 51 g/L; Total Protein 6.9 g/dL; Glucose 5.12 mmol/L.
- Day 704 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 9.13 mmol/L.
- Day 802 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Immunoglobulin G 6.26 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.8 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 46 g/L; Total Protein 6.5 g/dL; Glucose 15 mmol/L.
- Day 875 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 15.8 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 7.32 mmol/L.
- Day 972 (ECOG 0): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.163 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 3.3 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.89 µg/mL; Lactate Dehydrogenase 10.7 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 8.8 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 6.82 mmol/L.
- Day 1,063 (ECOG 0): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.92 mg/dL; Immunoglobulin G 9.43 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 4.11 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 5.56 mmol/L.
- Day 1,152 (ECOG 0): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 5.46 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 9.32 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 4.4 mmol/L.

Other clinical attributes
- Day -22: Weight: 93 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (3 samples)
- Sample MMRF_1730_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -22 days.
- Sample MMRF_1730_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -22 days.
- Sample MMRF_1730_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 704 days (1.9 years).
